CCDI case PBBVMB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/0186edfb-3f86-46a0-b3e6-9160e5388458

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.7 years (3,534 days).

Biospecimens (3 samples)
- Sample 0DI7SG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI7VC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DI7VK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
